Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8P5, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8P5-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- 1 - "Chain 8p lymph node":
- Absence of neoplasia in one lymph node (0/1).
- 2 - "Designated as chain 9 lymph nodes":
- Fragment of mature adipose tissue, uninvolved by neoplasia (0/0);
- 3 - "Gallbladder":
- Chronic cholecystitis with cholesterosis.
- 4 - "Stomach + omentum":
- Gastric adenocarcinoma, poorly differentiated, intestinal type, ulcerative vegetating, measuring 6.0 cm in greatest diameter located in the anterior wall of the gastric body, infiltrating the wall until the subserosa;
- Presence of perineural invasion;
- Angiolymphatic invasion not detected;
- Scarce peritumoral desmoplasia;
- Moderate peritumoral lymphocitary infiltrate;
- Surgical margins uninvolved by neoplasia;
- Presence of 33 lymph nodes in the perigastric adipose tissue uninvolved by neoplasia (0/33);
- Fragments of omentum consisting of mature adipose tissue, uninvolved by neoplasia.

ICD-O-3

Adenocarcinoma, intestinal
type 814413

Site: 4 Body of stomach C16.2

Sp 3/7/14

ICD-O Discrepancy		/
ICD-O Management History		/
Discrepancy Primary Site		/

Source: NCI Genomic Data Commons file 3cc9b798-57ad-4721-b861-ab12a389d057 (TCGA-VQ-A8P5.F72CB305-1710-41BC-95C0-F29F3547429F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).